Somatic mutation profile of tumor specimen TCGA-DE-A7U5-01A (aliquot TCGA-DE-A7U5-01A-11D-A397-08) from TCGA case TCGA-DE-A7U5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.7 years (13,411 days).
Specimen TCGA-DE-A7U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d64715-89ec-4f40-9409-467b65fec617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A7U5-10A (Blood Derived Normal), aliquot TCGA-DE-A7U5-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/113ca560-0e8e-415b-b322-7ecf6bc8ac13

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CELSR1 | c.7600G>T p.V2534F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV99418087; called by muse, mutect2
- SMARCC2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as COSV99911242; called by muse, mutect2, varscan2
- SPIN2B | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99328153; called by mutect2, varscan2
- THOC5 | c.1997G>C p.S666T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.054); catalogued as COSV100803566; called by muse, mutect2, varscan2
- CEP89 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- FAM169B | n.557A>G | RNA (SNP) | VAF 16/40 reads (40%) | catalogued as COSV60568550; called by muse, mutect2, varscan2
